Somatic mutation profile of tumor specimen MP2PRT-PAUSSA-TBP1-A (aliquot MP2PRT-PAUSSA-TBP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUSSA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,389 days).
Specimen MP2PRT-PAUSSA-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4b66b8b-620b-4fd5-9b36-697857e97555.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUSSA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUSSA-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21aba93d-3b28-402a-87cc-477be9b5dc2f

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, 3'Flank 1, Nonsense Mutation 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC099489.1 | c.2638G>A p.A880T | Missense Mutation (SNP) | VAF 238/786 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1038707044; called by muse, mutect2, varscan2
- DNAH3 | c.4042C>T p.R1348C | Missense Mutation (SNP) | VAF 111/358 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs377178771; called by muse, mutect2, varscan2
- HEXIM1 | c.101dup p.G35Rfs*12 | Frame Shift Ins (INS) | VAF 394/813 reads (48%) | catalogued as rs767170073; called by mutect2, pindel, varscan2
- KLHDC1 | c.663G>A p.M221I | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.426); catalogued as rs1566612828; called by muse, mutect2, varscan2
- MPDZ | c.4576G>A p.G1526R | Missense Mutation (SNP) | VAF 95/244 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs758008321; called by muse, mutect2, varscan2
- MYO16 | c.2747_2749del p.V916del | In Frame Del (DEL) | VAF 28/136 reads (21%) | catalogued as rs770254011; called by pindel, varscan2
- OR4C5 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 188/409 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs561798212; called by muse, mutect2, varscan2
- PLEKHG4 | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 191/640 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773077892; called by muse, mutect2, varscan2
- RAP1GAP2 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 123/273 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.656); catalogued as rs1249339568; called by muse, mutect2, varscan2
- VPS13C | c.3985C>T p.R1329W (on ENST00000644861 / NM_020821.3; = p.R1286W on NM_017684.5) | Missense Mutation (SNP) | VAF 99/335 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747568610; called by muse, mutect2, varscan2
- ARHGEF5 | c.77C>A p.A26D | Missense Mutation (SNP) | VAF 154/1627 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2
- CNNM1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 293/714 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- COL6A6 | c.3778A>T p.N1260Y | Missense Mutation (SNP) | VAF 156/366 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- DDX19A | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 490/767 reads (64%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DSP | c.6460A>C p.I2154L | Missense Mutation (SNP) | VAF 109/325 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- EYA4 | c.409C>A p.Q137K | Missense Mutation (SNP) | VAF 162/377 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- NICN1 | c.328A>T p.R110* | Nonsense Mutation (SNP) | VAF 132/204 reads (65%) | called by muse, varscan2
- TOMM40 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 179/433 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYA4 | c.1182C>T p.T394= (on ENST00000531901 / NM_001301013.1; = p.T388= on NM_004100.5) | Silent (SNP) | VAF 103/235 reads (44%) | catalogued as rs763994459; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMA2 | c.7206C>T p.Y2402= | Silent (SNP) | VAF 64/369 reads (17%) | catalogued as rs148313644; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPN21 | c.1710G>A p.P570= | Silent (SNP) | VAF 113/351 reads (32%) | catalogued as rs933642695, COSV60847212; called by muse, mutect2, varscan2
- RNF34 | c.108C>G p.T36= | Silent (SNP) | VAF 116/574 reads (20%) | catalogued as rs782086917; called by muse, mutect2, varscan2
- IGKV3D-11 | chr2:90173414 ins CA | 3'Flank (INS) | VAF 50/209 reads (24%) | called by pindel, varscan2*
